Somatic mutation profile of tumor specimen MBCProject_1542_T2_WES (aliquot MBCProject_1542_T2_WES_1) from CMI case MBCProject_1542, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.3 years (15,808 days).
Specimen MBCProject_1542_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ad0dc5-1460-47f2-925b-06bed38c192c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1542_SALIVA (Saliva), aliquot MBCProject_1542_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b0c3adf-7fe8-404b-92eb-a16660fbfcff

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Intron 2, Frame Shift Del 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD34 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60412982; called by muse, varscan2
- CDYL | c.380G>A p.R127K (on ENST00000328908 / NM_001368125.1; = p.R73K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as rs1170021646, COSV100188563; called by muse, mutect2
- NEFL | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99647989; called by muse, mutect2
- KRT25 | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MROH2B | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RIMS2 | c.753dup p.E252Rfs*17 (on ENST00000666250 / NM_001348490.2; = p.E60Rfs*17 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- RIMS2 | c.1405del p.T469Qfs*10 (on ENST00000666250 / NM_001348490.2; = p.T277Qfs*10 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/236 reads (11%) | called by pindel, varscan2
- RPH3A | c.102_118del p.V35Afs*2 (on ENST00000389385 / NM_001143854.2; = p.V31Afs*2 on NM_014954.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/64 reads (8%) | called by mutect2, pindel
- GTF3C4 | c.1227A>T p.A409= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV64644941; called by muse, mutect2
- PIK3R1 | c.570C>T p.L190= | Silent (SNP) | VAF 14/312 reads (4%) | catalogued as COSV99141804; called by muse, mutect2
- PLEC | c.4635G>A p.A1545= (on ENST00000322810 / NM_201380.4; = p.A1435= on NM_000445.5) | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs782548383; called by muse, mutect2, varscan2
- SMG6 | c.3432T>A p.P1144= | Silent (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- VARS1 | c.3678C>G p.G1226= | Silent (SNP) | VAF 34/396 reads (9%) | catalogued as COSV63304471; called by muse, mutect2
- DCAF17 | c.322-1195A>G | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PADI4 | c.340+562C>G | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs923868101; called by muse, varscan2
- PATJ | c.*1975C>G | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1178016157; called by mutect2, varscan2
